Somatic mutation profile of tumor specimen TCGA-BR-4371-01A (aliquot TCGA-BR-4371-01A-01D-1158-08) from TCGA case TCGA-BR-4371, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; Tumor grade: G1; Age at diagnosis: 72.0 years (26,290 days).
Specimen TCGA-BR-4371-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9ecd394-4b9a-4ea4-8f79-7ff597161d85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-4371-11A (Solid Tissue Normal), aliquot TCGA-BR-4371-11A-01D-1158-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2daefb5f-23ca-47cc-95a8-3cea47374ea2

The open-access MAF lists 160 somatic variants for this specimen: 116 protein-altering or splice-affecting, 40 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 99, Silent 40, Nonsense Mutation 13, Intron 2, Splice Site 2, RNA 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1635T>G p.Y545* (on ENST00000281708 / NM_001349798.2; = p.Y465* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 90/224 reads (40%) | hotspot (GDC flag); catalogued as COSV55956190; called by muse, mutect2, varscan2
- NF1 | c.1381C>T p.R461* | Nonsense Mutation (SNP) | VAF 88/190 reads (46%) | hotspot (GDC flag); catalogued as rs878853865, CM000780, COSV62194747; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.8017C>T p.Q2673* (on ENST00000358273 / NM_001042492.3; = p.Q2652* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 31/85 reads (36%) | catalogued as rs1567627751, COSV62221019; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 20/85 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 21/124 reads (17%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMAD2 | c.1391C>G p.S464* | Nonsense Mutation (SNP) | VAF 20/88 reads (23%) | hotspot (GDC flag); catalogued as COSV50992836, COSV50992894, COSV50993280; called by muse, mutect2, varscan2
- ZBTB7A | c.1271A>C p.K424T | Missense Mutation (SNP) | VAF 24/61 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59326753, COSV59327496; called by muse, mutect2, varscan2
- ADAM32 | c.1502G>A p.R501H | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as rs762485084, COSV65949924; called by muse, mutect2, varscan2
- ADAMTS10 | c.1934C>T p.A645V | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54357115; called by muse, mutect2, varscan2
- ASTN2 | c.1267C>T p.R423C (on ENST00000313400 / NM_001365069.1; = p.R372C on NM_014010.5) | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs949313564, COSV57753974; called by muse, mutect2, varscan2
- ATP1A4 | c.2083G>A p.V695M | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs775399497, COSV63628457; called by muse, mutect2, varscan2
- BEST3 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.108); catalogued as rs372783693; called by muse, mutect2, varscan2
- BIRC7 | c.881G>A p.R294H (on ENST00000217169 / NM_139317.3; = p.R276H on NM_022161.4) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.209); catalogued as rs142521563; called by muse, mutect2
- BRWD1 | c.6862G>A p.D2288N | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.755); catalogued as COSV59001355; called by muse, mutect2, varscan2
- BTBD1 | c.130C>G p.P44A | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV55604766; called by muse, mutect2, varscan2
- BUD13 | c.1150C>T p.R384W | Missense Mutation (SNP) | VAF 67/147 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); catalogued as rs149005278; called by muse, mutect2, varscan2
- C1orf141 | c.985G>T p.V329L | Missense Mutation (SNP) | VAF 62/176 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV63993363; called by muse, mutect2, varscan2
- CACNA1A | c.6158C>T p.P2053L | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.87); PolyPhen benign (0.066); catalogued as rs539347883, COSV100801628, COSV64211959; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CARHSP1 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as rs201523233, COSV100220146, COSV60683801; called by muse, mutect2, varscan2
- CFH | c.210A>C p.E70D | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as COSV62778803; called by muse, mutect2
- CHD7 | c.8869G>A p.D2957N | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.959); catalogued as rs762553908, COSV71114384; called by muse, mutect2, varscan2
- CHRM2 | c.379A>G p.K127E | Missense Mutation (SNP) | VAF 40/215 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV57784160; called by muse, mutect2, varscan2
- COL5A2 | c.4171C>T p.R1391C | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759098736, COSV66409370; called by muse, mutect2, varscan2
- CPEB4 | c.1683G>T p.W561C | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54175961; called by muse, mutect2, varscan2
- CTSF | c.963G>A p.Q321= | Splice Region (SNP) | VAF 49/113 reads (43%) | catalogued as COSV59750429; called by muse, mutect2, varscan2
- CTTN | c.1381G>A p.G461S | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV100098245; called by muse, mutect2, varscan2
- CUBN | c.9443G>A p.R3148Q | Missense Mutation (SNP) | VAF 46/369 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs746738635, COSV64720860; called by muse, mutect2, varscan2
- CXCR5 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs762687395, COSV52684140; called by muse, mutect2, varscan2
- DKK3 | c.739C>T p.R247W | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs200187644; called by muse, mutect2, varscan2
- DNAH10 | c.9220C>T p.R3074C (on ENST00000409039; = p.R3013C on NM_207437.3) | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375220630; called by muse, mutect2, varscan2
- DNAH9 | c.7978C>T p.Q2660* | Nonsense Mutation (SNP) | VAF 67/293 reads (23%) | catalogued as COSV52351356, COSV52375841; called by muse, mutect2, varscan2
- DOCK11 | c.3097C>T p.R1033C | Missense Mutation (SNP) | VAF 76/267 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs377535991, COSV52247323; called by muse, mutect2, varscan2
- DOCK2 | c.4592T>C p.L1531P | Missense Mutation (SNP) | VAF 41/192 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56986791; called by muse, mutect2, varscan2
- DOCK2 | c.4977C>A p.S1659R | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV56986804; called by muse, mutect2, varscan2
- DRD5 | c.156C>G p.I52M | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV58577520, COSV58580334; called by muse, varscan2
- EIF3G | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 75/262 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV53455985; called by muse, mutect2, varscan2
- ENTPD7 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.746); catalogued as rs745552200, COSV65112702, COSV65113240; called by muse, mutect2, varscan2
- EPHA4 | c.376T>C p.Y126H | Missense Mutation (SNP) | VAF 51/245 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1311349395, COSV56028853; called by muse, mutect2, varscan2
- FAM234B | c.793C>A p.P265T | Missense Mutation (SNP) | VAF 196/498 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52197417, COSV99545884; called by muse, mutect2, varscan2
- FAM71B | c.1026C>A p.S342R | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs762666022, COSV57230919; called by muse, mutect2, varscan2
- FKBP4 | c.1309G>A p.D437N | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as COSV50009966; called by muse, mutect2, varscan2
- FREM2 | c.1402T>G p.L468V | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV54826828, COSV54842467; called by muse, mutect2, varscan2
- FSD2 | c.1241A>C p.D414A | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as COSV58012896; called by muse, mutect2, varscan2
- GPC5 | c.1533A>C p.E511D | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.949); catalogued as COSV65628522; called by muse, mutect2, varscan2
- GPR4 | c.43G>A p.V15M | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.584); catalogued as rs763872953, COSV59918250; called by muse, mutect2, varscan2
- GRHPR | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV58945005; called by muse, mutect2, varscan2
- HECW1 | c.239C>T p.T80M | Missense Mutation (SNP) | VAF 74/132 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754051189, COSV67828819; called by muse, mutect2, varscan2
- HHAT | c.1124T>C p.V375A | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54808987; called by muse, mutect2, varscan2
- HIPK4 | c.478G>A p.G160R | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52525404; called by muse, mutect2, varscan2
- ICAM2 | c.395T>C p.I132T | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs370443111; called by muse, mutect2, varscan2
- IGSF1 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 102/265 reads (38%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.996); catalogued as rs149790689, COSV63837202; called by muse, mutect2, varscan2
- JPH4 | c.1307C>T p.T436M | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as rs767075479, COSV58113445; called by muse, mutect2, varscan2
- KCNB1 | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 50/229 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779573636, COSV65566374; called by muse, mutect2, varscan2
- KLC2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs571985017, COSV57584272; called by muse, varscan2
- KRTAP11-1 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as rs532579531, COSV60094276; called by muse, mutect2, varscan2
- LAMC3 | c.2260C>A p.P754T | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs371563171, COSV63095282; called by muse, mutect2, varscan2
- LHX9 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV61329835; called by muse, mutect2, varscan2
- LILRA2 | c.1355G>A p.R452H (on ENST00000391738 / NM_001130917.3; = p.R435H on NM_006866.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as rs199988092, COSV52191718; called by muse, mutect2, varscan2
- LRCH4 | c.1930C>T p.R644W | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs748668021, COSV56166799; called by muse, mutect2, varscan2
- LRP2 | c.10922G>A p.R3641Q | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0.196); catalogued as COSV55573309; called by muse, mutect2, varscan2
- MAGEB6 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 96/168 reads (57%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.759); catalogued as rs200923993, COSV66872390, COSV66872804; called by muse, mutect2, varscan2
- MAP1B | c.3824G>A p.R1275H | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as rs372421201; called by muse, mutect2, varscan2
- MIP | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.03); catalogued as rs770704370, COSV57515047; called by muse, mutect2, varscan2
- MKRN3 | c.1368G>T p.M456I | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV58812056; called by muse, mutect2, varscan2
- MRPL39 | c.530G>A p.G177D | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1272352108, COSV56262099; called by muse, mutect2, varscan2
- NAB2 | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.585); catalogued as rs1029066357, COSV55667921; called by muse, mutect2, varscan2
- NUP107 | c.2284G>A p.E762K | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.088); catalogued as COSV57497962; called by muse, mutect2, varscan2
- OGDHL | c.1468G>A p.V490M | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1167099402, COSV65104580; called by muse, mutect2, varscan2
- OR4M1 | c.665T>C p.L222P | Missense Mutation (SNP) | VAF 49/460 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs148618328; called by muse, mutect2, varscan2
- PCDH18 | c.3082G>T p.E1028* | Nonsense Mutation (SNP) | VAF 37/90 reads (41%) | catalogued as COSV61271972; called by muse, mutect2, varscan2
- PCDHA1 | c.2230G>A p.A744T | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.024); catalogued as COSV65372998, COSV65375231; called by muse, mutect2, varscan2
- PCDHGA5 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 31/198 reads (16%) | catalogued as COSV54027796; called by muse, mutect2, varscan2
- PCDHGA6 | c.1207C>T p.R403* | Nonsense Mutation (SNP) | VAF 19/118 reads (16%) | catalogued as rs763674664, COSV53901357; called by muse, mutect2, varscan2
- PITX2 | c.406C>T p.R136C (on ENST00000354925 / NM_001204397.1; = p.R143C on NM_000325.6) | Missense Mutation (SNP) | VAF 44/227 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM004057, COSV60741967; called by muse, mutect2, varscan2
- PLCE1 | c.5881C>T p.R1961* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as rs774196868, COSV53371264; called by muse, mutect2, varscan2
- PLEKHG6 | c.2173G>C p.A725P | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1451226644, COSV50612270; called by muse, mutect2, varscan2
- POLR2B | c.1733A>T p.K578I | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV58902653; called by muse, mutect2, varscan2
- PPP4R4 | c.247C>T p.R83* | Nonsense Mutation (SNP) | VAF 33/73 reads (45%) | catalogued as rs1268987676, COSV58558132; called by muse, mutect2, varscan2
- PREX2 | c.2185A>T p.K729* | Nonsense Mutation (SNP) | VAF 136/224 reads (61%) | catalogued as COSV55797791; called by muse, mutect2, varscan2
- PRICKLE2 | c.1526C>T p.S509L (on ENST00000295902; = p.S453L on NM_198859.4) | Missense Mutation (SNP) | VAF 39/231 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.3); catalogued as rs767820294, COSV55771515; called by muse, mutect2, varscan2
- PTGER2 | c.695G>A p.S232N | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV55420117; called by muse, mutect2, varscan2
- PTPRJ | c.3051-1G>T p.X1017_splice | Splice Site (SNP) | VAF 56/127 reads (44%) | catalogued as rs1042660430, COSV69254567; called by muse, mutect2, varscan2
- RELN | c.3619G>A p.E1207K | Missense Mutation (SNP) | VAF 279/529 reads (53%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.952); catalogued as COSV59032765; called by muse, mutect2, varscan2
- RNF103 | c.92G>A p.G31D | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52896967; called by muse, mutect2, varscan2
- RP1 | c.4535A>C p.K1512T | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV55126169; called by muse, mutect2, varscan2
- RPS6KA1 | c.1588G>C p.G530R | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs760553222, COSV65177767; called by muse, mutect2, varscan2
- RYR3 | c.3599G>A p.R1200H | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.774); catalogued as rs377298605, COSV66777971; called by muse, mutect2, varscan2
- SEC61A1 | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 24/85 reads (28%) | catalogued as COSV54575620; called by muse, mutect2, varscan2
- SERPINB12 | c.674C>T p.T225M | Missense Mutation (SNP) | VAF 109/179 reads (61%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs200518644, COSV54032923, COSV54035304; called by muse, mutect2, varscan2
- SIGLEC5 | c.1498G>A p.G500R | Missense Mutation (SNP) | VAF 53/306 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs759409207, COSV55783795; called by muse, mutect2, varscan2
- SLC14A2 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 85/157 reads (54%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.054); catalogued as rs763235524, COSV54907449, COSV99676309; called by muse, mutect2, varscan2
- SLC16A4 | c.145C>T p.Q49* | Nonsense Mutation (SNP) | VAF 35/196 reads (18%) | catalogued as COSV63917363; called by muse, mutect2, varscan2
- SLC1A3 | c.1419G>T p.W473C | Missense Mutation (SNP) | VAF 66/193 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54320254; called by muse, mutect2, varscan2
- SLC5A1 | c.614C>T p.T205I | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.517); catalogued as COSV56686774; called by muse, varscan2
- SLITRK6 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 23/237 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs200364181, COSV68389686; called by muse, mutect2
- SMOC2 | c.282G>C p.R94S | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV62444068, COSV62445524; called by muse, varscan2
- SP1 | c.266G>A p.G89E (on ENST00000327443 / NM_138473.3; = p.G82E on NM_003109.1) | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as rs773597100, COSV59405133; called by muse, mutect2, varscan2
- SPATA6 | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 74/280 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs187921034, COSV64058154; called by muse, mutect2, varscan2
- TBC1D9B | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 123/279 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs568744817, COSV62283956; called by muse, mutect2, varscan2
- TBX5 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59865162; called by muse, mutect2, varscan2
- TECTB | c.889G>A p.V297M | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs749582234, COSV65596470; called by muse, mutect2, varscan2
- TEX15 | c.6664G>T p.D2222Y (on ENST00000256246; = p.D2605Y on NM_001350162.2) | Missense Mutation (SNP) | VAF 48/313 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56353391; called by muse, mutect2, varscan2
- TGFB2 | c.1141G>A p.V381M | Missense Mutation (SNP) | VAF 66/262 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376159002; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TLK1 | c.2251G>A p.G751R | Missense Mutation (SNP) | VAF 51/243 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.475); catalogued as COSV62632903; called by muse, mutect2, varscan2
- TMTC1 | c.2443G>A p.A815T (on ENST00000539277 / NM_001193451.2; = p.A707T on NM_175861.3) | Missense Mutation (SNP) | VAF 81/256 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV55493182; called by muse, mutect2, varscan2
- TNN | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV53435120; called by muse, mutect2, varscan2
- TPTE2 | c.1524T>G p.I508M (on ENST00000400230 / NM_199254.2; = p.I431M on NM_130785.3) | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as rs780874714, COSV55027931; called by muse, mutect2, varscan2
- TRPA1 | c.1965+1G>T p.X655_splice | Splice Site (SNP) | VAF 21/186 reads (11%) | catalogued as COSV51562839; called by muse, mutect2, varscan2
- TRRAP | c.2947G>A p.A983T | Missense Mutation (SNP) | VAF 89/303 reads (29%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs972402682, COSV100722685, COSV62841564; called by muse, mutect2, varscan2
- TTN | c.48583C>T p.R16195C (on ENST00000591111; = p.R8771C on NM_003319.4) | Missense Mutation (SNP) | VAF 47/255 reads (18%) | PolyPhen probably damaging (0.998); catalogued as rs376153809; called by muse, mutect2, varscan2
- UBE4B | c.1381C>T p.R461C (on ENST00000343090 / NM_001105562.3; = p.R332C on NM_006048.5) | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs751961761, COSV53541956; called by muse, mutect2, varscan2
- ZDHHC6 | c.610G>C p.A204P | Missense Mutation (SNP) | VAF 68/224 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV65565149; called by muse, mutect2, varscan2
- ZFP2 | c.1304A>G p.E435G | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63726952; called by muse, mutect2, varscan2
- ZNF81 | c.1442C>A p.S481Y | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as COSV58578589, COSV58579144; called by muse, mutect2, varscan2
- GGNBP2 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 53/125 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- MRM1 | c.888A>G p.A296= | Splice Region (SNP) | VAF 17/76 reads (22%) | called by muse, mutect2, varscan2
- ABCB11 | c.2730C>T p.F910= | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as COSV55600586; called by muse, mutect2, varscan2
- AC136428.1 | c.279C>T p.N93= | Silent (SNP) | VAF 83/424 reads (20%) | catalogued as rs1035006412, COSV71169258; called by muse, mutect2, varscan2
- ADAMTS17 | c.1416C>T p.A472= | Silent (SNP) | VAF 32/163 reads (20%) | catalogued as COSV51493190; called by muse, mutect2, varscan2
- AFF3 | c.3432G>A p.P1144= | Silent (SNP) | VAF 25/144 reads (17%) | catalogued as rs200904404; called by muse, mutect2, varscan2
- APBA2 | c.72T>A p.P24= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as COSV68795179; called by muse, mutect2, varscan2
- ARID3B | c.532C>T p.L178= | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as COSV60559080; called by muse, mutect2, varscan2
- ASAP1 | c.1902G>A p.T634= | Silent (SNP) | VAF 27/200 reads (14%) | catalogued as rs753375926, COSV63054255; called by muse, mutect2, varscan2
- AZU1 | c.321C>T p.Y107= | Silent (SNP) | VAF 57/154 reads (37%) | catalogued as rs757880401, COSV52142573; called by muse, mutect2, varscan2
- BPIFC | c.870G>A p.A290= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as rs376253753; called by muse, mutect2, varscan2
- CDKL5 | c.3021G>T p.L1007= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as COSV66107439; called by muse, mutect2, varscan2
- COL5A1 | c.5433C>A p.P1811= | Silent (SNP) | VAF 18/115 reads (16%) | catalogued as COSV65674456; called by muse, mutect2, varscan2
- COL7A1 | c.4944G>A p.P1648= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs111360822, COSV100097309; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOXB1 | c.291C>T p.F97= | Silent (SNP) | VAF 33/101 reads (33%) | catalogued as COSV68526467; called by muse, mutect2, varscan2
- HCN1 | c.2475G>A p.T825= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as COSV57532440, COSV57534071; called by muse, mutect2, varscan2
- NKX2-1 | c.423C>T p.G141= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV61390233; called by muse, mutect2, varscan2
- NRXN1 | c.840A>G p.E280= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV58490683; called by muse, mutect2, varscan2
- NUMA1 | c.6156C>T p.I2052= | Silent (SNP) | VAF 84/212 reads (40%) | catalogued as COSV52622639; called by muse, mutect2, varscan2
- OR5D16 | c.717C>A p.V239= | Silent (SNP) | VAF 25/188 reads (13%) | catalogued as rs764583326, COSV101003946, COSV65722925; called by muse, mutect2, varscan2
- PCDH10 | c.912G>A p.S304= | Silent (SNP) | VAF 59/120 reads (49%) | catalogued as rs1393393178, COSV52086871, COSV52103524; called by muse, mutect2, varscan2
- PIK3CG | c.3075C>T p.N1025= | Silent (SNP) | VAF 37/382 reads (10%) | catalogued as COSV63253384; called by muse, mutect2, varscan2
- PLPPR5 | c.81G>A p.A27= | Silent (SNP) | VAF 56/113 reads (50%) | catalogued as COSV54178421; called by muse, mutect2, varscan2
- POMC | c.111C>T p.L37= | Silent (SNP) | VAF 10/172 reads (6%) | catalogued as COSV53035662; called by muse, mutect2
- RALGDS | c.1830G>A p.S610= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as rs1466061009, COSV64429535; called by muse, mutect2, varscan2
- RIMS2 | c.2637A>G p.P879= (on ENST00000666250 / NM_001348490.2; = p.P687= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 18/176 reads (10%) | catalogued as COSV99191811; called by muse, varscan2
- RNF150 | c.588A>G p.G196= | Silent (SNP) | VAF 74/338 reads (22%) | catalogued as COSV60799214; called by muse, mutect2, varscan2
- SAMHD1 | c.681G>A p.P227= | Silent (SNP) | VAF 32/310 reads (10%) | catalogued as rs144587056; called by muse, mutect2
- SCN2A | c.5088C>T p.N1696= | Silent (SNP) | VAF 41/368 reads (11%) | catalogued as rs560341706, COSV51854688; called by muse, mutect2, varscan2
- SEC14L1 | c.1962C>T p.D654= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs904654445, COSV66721044; called by muse, mutect2, varscan2
- SLC17A7 | c.147G>A p.P49= | Silent (SNP) | VAF 40/187 reads (21%) | catalogued as rs767678777, COSV55550047; called by muse, mutect2, varscan2
- SYCP2 | c.1905G>A p.S635= | Silent (SNP) | VAF 13/161 reads (8%) | catalogued as rs377052965; called by muse, mutect2
- TIE1 | c.1758C>T p.D586= | Silent (SNP) | VAF 37/102 reads (36%) | catalogued as rs201759080; called by muse, mutect2, varscan2
- TOM1L2 | c.285C>T p.I95= | Silent (SNP) | VAF 44/117 reads (38%) | catalogued as rs746685451, COSV58885879; called by muse, mutect2, varscan2
- TRHDE | c.585C>T p.A195= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as COSV53865003; called by muse, mutect2, varscan2
- UBTD1 | c.450G>T p.P150= | Silent (SNP) | VAF 8/116 reads (7%) | catalogued as COSV100080824, COSV53969581; called by muse, mutect2
- XIRP2 | c.4122C>A p.G1374= (on ENST00000628543; = p.G1549= on NM_152381.6) | Silent (SNP) | VAF 38/125 reads (30%) | catalogued as COSV54732880; called by muse, mutect2, varscan2
- ZIC1 | c.384C>T p.F128= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV51557793; called by muse, mutect2, varscan2
- ZNF317 | c.1728C>T p.H576= | Silent (SNP) | VAF 20/140 reads (14%) | catalogued as rs1444282125, COSV56111498; called by muse, mutect2, varscan2
- ZNF366 | c.543C>T p.H181= | Silent (SNP) | VAF 48/270 reads (18%) | catalogued as COSV59218956; called by muse, mutect2, varscan2
- ZNF691 | c.795C>T p.S265= (on ENST00000372502; = p.S234= on NM_015911.3) | Silent (SNP) | VAF 29/129 reads (22%) | catalogued as rs532331174, COSV65289724; called by muse, mutect2, varscan2
- ZNF704 | c.1233C>T p.L411= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs1157139053, COSV59919999; called by muse, varscan2
- C8orf31 | n.678C>T | RNA (SNP) | VAF 12/93 reads (13%) | catalogued as rs1250328499; called by muse, mutect2, varscan2
- CHRM2 | c.-47+33755C>A | Intron (SNP) | VAF 80/286 reads (28%) | catalogued as rs375768209; called by muse, mutect2, varscan2
- RPL30 | c.299-253T>C | Intron (SNP) | VAF 13/219 reads (6%) | catalogued as COSV99750512; called by muse, mutect2
- SLC22A17 | n.717G>A | RNA (SNP) | VAF 12/42 reads (29%) | catalogued as rs750576654, COSV52837377; called by muse, mutect2, varscan2
